Surgical pathology report (de-identified scan), TCGA case TCGA-66-2744, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2744-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Right lower lobe

Clinical diagnosis and question

Suspected BC of the right lower lobe segment 8, status post epiglottis carcinoma.

REPORT ON FINDINGS**Macroscopy**

1.) Peribronchial lower lobe bronchus: 0.3 cm pale section.
2.) Inflated, fixed right lower lobe measuring 16 x 12 cm at the base and up to 18.5 cm in length, central bronchus resection line located at the bifurcation of B6. Staple suture lines measuring 4.5 and 3.5 cm, respectively, run from the hilus to the cranial and the ventrocaudal regions. At the hilus two mobile lesioned grayish-black nodes, 0.6 and 0.8 cm in size. Moderately solid pale brownish-white tumor max. 3.8 cm in size with unclear demarcation and patchy blackish pigmentation located in the central region at the bifurcation of B8. Narrowing of B8 and its proximal subsegmental branches. Involvement of some blackish pigmented nodes up to 1.2 cm in size by the tumor, one of these at the hilus. Tumor distance from hilar resection surface at least 0.1 cm, extends right up to the peripheral pleura. Sleeve-like tumor spread along smaller bronchial branches. Peripheral bronchi in segment 8 dilated and filled with thick mucus. Parenchyma in tumor environment diffusely indurated in places and of brownish-yellow color. Rest of parenchyma, pleura and prepared bronchial pathways inconspicuous.

- 1.) Lobar LN (Item 12) middle lobe: 1.2 cm lesioned grayish-black node or node part.
- 2.) Lobar LN (Item 12) middle lobe: 1.3 cm lesioned grayish-black node or node part.
- 3.) Hilar LN (Item 10) right: 2.5 cm lesioned grayish-black node.
- 4.) Subcarinal LN (Item 7): two lesioned grayish-black nodes with some surrounding tissue, 0.6 and 3 cm in size, the larger one strand-shaped.

Examined:

- 1.) Rapid section residual material,
- 2.) Tumor with rest of parenchyma, with subsegmental branches of B8 and involved nodes, tumor margin area with sleeve-like spread, hilar resection surface (color marking), 2 sections with peripheral pleura + hilar nodes, central bronchus resection line + resection margins vessels, mobile hilar nodes,
- 3.) Rapid section remains + residual material,
- 4.) - 6.) all material (in 5. preparation, in 6. largest node multi-segmented), 12 blocks, partly Elastica van Gieson, PAS, and diastase-PAS.

Microscopy

- 1.) Immediate intraoperative evaluation (): mainly vessel, marginal very small LN section without tumor.
- 3.) Immediate intraoperative evaluation (): LN with no carcinoma.

Description of histological and cytological findings omitted for capacity reasons.

[page 2 of 2]
EVALUATION

Primary diagnosis/diagnoses

Bronchopulmonary, histologically large-cell solid carcinoma without mucin formation extending from central to peripheral areas in the region of the mediastinal pleura. Tumor classification according to this picture pT2 pN1 V1 R0, stage IIB. C343 M8012/3 or 8070/3.

Secondary diagnosis/diagnoses

Tumor necrosis. Marked, largely interstitial chronic and predominantly lymphofollicular inflammation in the area of the tumor margin with atypical adenomatous alveolar hyperplasia. Chronic sclerotic peribronchitis of downstream subsegmental bronchi and active chronic peripheral bronchitis in S8. Tumor-free lymph nodes with moderate anthracotic pigment deposit and reactive follicular hyperplasia.

Remark/addendum

The carcinoma lies in S8; it probably developed centrally with partial infiltration and destruction of B8. Medium-sized pulmonary arteries are infiltrated by the tumor, focally destroyed and obliterated; there is also a focal tumor infiltration of the outer wall of the main branch of the pulmonary artery to the lower lobe. The resection margins of the large pulmonary vessels and the bronchus resection line are tumor-free. The lymph node metastases lie in the region of the primary tumor and the hilar region. Since histological examination occasionally shows vaguely suggestive differentiation or structural features of squamous cell carcinoma, it could also be an undifferentiated squamous cell carcinoma (immunohistochemical cytokeratin analysis follows).

Material examined:

Right lower lobe

1. Additional report

Immunohistochemical studies

The marker profile established (positive for CK7 and to some extent high molecular weight keratins, negative for TTF-1) is consistent with (undifferentiated) squamous cell carcinoma.

Source: NCI Genomic Data Commons file 601d05ff-86ab-4c35-b0d1-afcaa3aca4d9 (TCGA-66-2744.75AD62A3-0CF4-45EF-A1CF-4C710A3368D3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).